Somatic mutation profile of tumor specimen MMRF_1726_1_BM_CD138pos (aliquot MMRF_1726_1_BM_CD138pos_T1_KBS5U_L05072) from MMRF case MMRF_1726, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.7 years (27,284 days).
Specimen MMRF_1726_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bc93d45-6a9b-474a-9da1-35e9775ba1db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1726_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1726_2_PB_Whole_C1_KBS5U_L05080; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd7b4180-f760-4974-8f74-6e39e214b43f

The open-access MAF lists 115 somatic variants for this specimen: 61 protein-altering or splice-affecting, 6 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 30, Intron 8, 5'UTR 6, Silent 6, Splice Region 4, Frame Shift Del 3, Nonsense Mutation 3, RNA 2, Splice Site 2, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71151491; called by muse, mutect2, varscan2
- BICRAL | c.2769C>G p.S923R | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.206); catalogued as COSV58408548; called by muse, mutect2
- CFAP46 | c.3277G>A p.G1093R | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs989142342, COSV63950290; called by muse, mutect2, varscan2
- COMP | c.216C>T p.C72= | Splice Region (SNP) | VAF 25/484 reads (5%) | catalogued as COSV55875935; called by muse, mutect2
- CSMD1 | c.5848G>T p.G1950C (on ENST00000520002; = p.G1949C on NM_033225.6) | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59285157; called by muse, mutect2, varscan2
- DNAH2 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758169548; called by muse, mutect2, varscan2
- FASTK | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 110/166 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs751845696; called by muse, mutect2, varscan2
- IGHJ4 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 30/36 reads (83%) | PolyPhen benign (0.046); catalogued as rs377431969; called by muse, varscan2
- IGKV3-20 | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.383); catalogued as rs533158281; called by muse, mutect2, varscan2
- IGLV4-3 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 43/126 reads (34%) | catalogued as rs200929155; called by muse, varscan2
- MSX1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs1425150458; called by muse, mutect2, varscan2
- MTF2 | c.1544T>C p.I515T | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.415); catalogued as rs868639197; called by muse, mutect2
- NIF3L1 | c.289T>C p.F97L (on ENST00000409020 / NM_001369444.1; = p.F70L on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53768582; called by muse, mutect2, varscan2
- NOS2 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767806769, COSV100569683; called by muse, mutect2, varscan2
- PCDH10 | c.2232G>T p.K744N | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs199885169, COSV52102097, COSV52104380; called by muse, mutect2
- PEAK1 | c.5241A>C p.*1747Yext*5 | Nonstop Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as rs760055004; called by muse, mutect2, varscan2
- RIMS4 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.055); catalogued as rs749628393, COSV65720168; called by muse, mutect2, varscan2
- SLCO2B1 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs764985441, COSV56935085; called by muse, mutect2, varscan2
- TAF1L | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 84/333 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs764175922, COSV54267502, COSV99644025; called by muse, mutect2, varscan2
- TGM7 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1367052982, COSV71772554; called by muse, mutect2, varscan2
- TRDN | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs1440512365; called by muse, mutect2
- TRPC5 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53300095; called by muse, mutect2
- TRPM2 | c.4174C>T p.R1392W | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.528); catalogued as rs372282416; called by muse, mutect2, varscan2
- TTC39B | c.2030G>A p.R677K | Missense Mutation (SNP) | VAF 19/514 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1282355216; called by muse, mutect2
- ABLIM3 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 111/169 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); called by muse, varscan2
- ACY3 | c.399A>T p.E133D | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASAH2 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ATG16L2 | c.895_899del p.K299Efs*10 | Frame Shift Del (DEL) | VAF 94/272 reads (35%) | called by mutect2, pindel, varscan2
- ATG4B | c.209_210del p.T70Rfs*141 | Frame Shift Del (DEL) | VAF 52/120 reads (43%) | called by pindel, varscan2
- ATP8B1 | c.2094A>C p.L698F | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf16 | c.4642A>G p.R1548G | Missense Mutation (SNP) | VAF 90/162 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CCDC39 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.86); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CD3D | c.247del p.E83Nfs*61 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- CENPI | c.365-1G>T p.X122_splice | Splice Site (SNP) | VAF 53/81 reads (65%) | called by muse, mutect2, varscan2
- CHD6 | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CNTN2 | c.488-5C>A | Splice Region (SNP) | VAF 85/271 reads (31%) | called by muse, mutect2, varscan2
- CNTN2 | c.2125+7G>A | Splice Region (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- CYLD | c.2470-1G>C p.X824_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- GLT1D1 | c.736G>A p.V246M (on ENST00000442111 / NM_001366889.1; = p.V166M on NM_144669.3) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- HARS1 | c.397-4T>C | Splice Region (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- IGHD2-8 | c.6A>G p.I2M | Missense Mutation (SNP) | VAF 57/58 reads (98%) | called by muse, varscan2
- IGHD2-8 | c.2G>C p.R1T | Missense Mutation (SNP) | VAF 60/61 reads (98%) | called by muse, varscan2
- IGKJ2 | chr2:88861519 del ACTTACGTTTGATCTCCAGCTTGGTCC | Missense Mutation (DEL) | VAF 38/45 reads (84%) | called by muse*, pindel, varscan2*
- IGLV4-3 | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.711); called by muse, varscan2
- IRF4 | c.1052A>G p.E351G | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRC30 | c.545T>A p.V182E | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- MMP14 | c.1164G>A p.W388* | Nonsense Mutation (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- PCDHGB2 | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 11/285 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- RTN1 | c.719A>T p.D240V | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2
- SLC12A5 | c.1214G>C p.G405A (on ENST00000454036 / NM_001134771.2; = p.G382A on NM_020708.5) | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO2B1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOCS1 | c.272A>C p.E91A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STIM2 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SUSD6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- TUT1 | c.1982T>G p.L661R | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- UGT2A1 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- UMODL1 | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- UNC80 | c.5789A>C p.N1930T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- VSTM5 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ZNF257 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- FAM237A | c.270G>C p.L90= | Silent (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- G3BP1 | c.1129T>C p.L377= | Silent (SNP) | VAF 62/198 reads (31%) | called by muse, mutect2, varscan2
- GRIK2 | c.2487C>T p.A829= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs370196358; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ROBO2 | c.900A>G p.G300= | Silent (SNP) | VAF 60/231 reads (26%) | called by muse, mutect2, varscan2
- SPATA13 | c.1041C>T p.N347= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10545T>C p.Y3515= | Silent (SNP) | VAF 25/398 reads (6%) | called by muse, mutect2
- AAMP | c.122-42C>G | Intron (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- ADGRG3 | c.*192G>A | 3'UTR (SNP) | VAF 33/36 reads (92%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.*3989C>A | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- C7orf33 | c.*78A>C | 3'UTR (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- CACNB2 | c.*608_*611del | 3'UTR (DEL) | VAF 4/39 reads (10%) | catalogued as rs1279312223; called by mutect2, pindel*
- CCND1 | c.415-16C>A | Intron (SNP) | VAF 13/32 reads (41%) | called by muse, varscan2
- CILK1 | c.*3337A>G | 3'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- COL15A1 | c.*473C>T | 3'UTR (SNP) | VAF 35/125 reads (28%) | catalogued as rs749971865; called by muse, mutect2, varscan2
- ENTPD5 | c.*2286del | 3'UTR (DEL) | VAF 27/38 reads (71%) | called by mutect2, pindel, varscan2
- FAM216B | c.*1010T>G | 3'UTR (SNP) | VAF 38/42 reads (90%) | called by muse, mutect2, varscan2
- FGFR1 | c.936+212C>T | Intron (SNP) | VAF 74/227 reads (33%) | called by muse, mutect2, varscan2
- GSPT1 | c.-82A>G | 5'UTR (SNP) | VAF 27/69 reads (39%) | called by muse, varscan2
- HCN3 | c.*299C>T | 3'UTR (SNP) | VAF 151/256 reads (59%) | called by muse, mutect2, varscan2
- HMGA2 | c.*546G>A | 3'UTR (SNP) | VAF 8/86 reads (9%) | catalogued as rs930285842; called by muse, mutect2
- HSD11B1L | c.669-59G>A | Intron (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- HTR1A | c.-430G>T | 5'UTR (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- KCNK5 | c.*295_*297del | 3'UTR (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- LSM11 | c.*4520G>T | 3'UTR (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- LYSMD4 | c.*1489_*1494del | 3'UTR (DEL) | VAF 43/83 reads (52%) | called by mutect2, pindel, varscan2
- MIR376A1 | n.37A>T | RNA (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- MIR513A1 | n.44G>T | RNA (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- NIM1K | c.-524A>G | 5'UTR (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- NOG | c.-145C>T | 5'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- PAK2 | c.*3372A>G | 3'UTR (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- PCDH15 | c.*458C>A | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- PDE4D | c.*2167G>A | 3'UTR (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2
- PDE4D | c.*2165A>G | 3'UTR (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2
- PGAP1 | c.*5128T>C | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- PIK3R1 | c.*248T>C | 3'UTR (SNP) | VAF 31/98 reads (32%) | catalogued as rs953915516; called by muse, mutect2, varscan2
- PTPN18 | c.*2100G>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- RANBP17 | c.2231+174T>A | Intron (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- RNF11 | c.*1459A>C | 3'UTR (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- RNF34 | c.-50A>G | 5'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as rs529512856; called by muse, mutect2, varscan2
- SAMD5 | c.*412T>C | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- SARDH | c.1020+518C>T | Intron (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- SDK2 | c.*2133A>G | 3'UTR (SNP) | VAF 11/109 reads (10%) | catalogued as rs1025704859; called by muse, mutect2
- SEPHS2 | c.*486A>G | 3'UTR (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- SLC11A1 | c.500+32C>T | Intron (SNP) | VAF 33/95 reads (35%) | catalogued as rs1232560221; called by muse, mutect2, varscan2
- SLC9A8 | c.*2766A>G | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ST6GAL2 | c.*3042G>C | 3'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, varscan2
- TMEM9 | c.-82G>A | 5'UTR (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- TMSB4X | chrX:12975604 C>T | 5'Flank (SNP) | VAF 73/78 reads (94%) | catalogued as COSV66082081; called by muse, mutect2, varscan2
- TPM4 | c.*391-139C>T | Intron (SNP) | VAF 10/21 reads (48%) | catalogued as rs564177754; called by muse, varscan2
- TRIO | c.*877A>G | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- VAPB | c.*6653T>A | 3'UTR (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- VASH2 | chr1:212989959 del AG | 3'Flank (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- VAV3 | c.*455T>A | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- VWA1 | c.*2247C>T | 3'UTR (SNP) | VAF 121/220 reads (55%) | called by muse, mutect2, varscan2
